Somatic mutation profile of tumor specimen MP2PRT-PANUCP-TMP1-A (aliquot MP2PRT-PANUCP-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANUCP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,251 days).
Specimen MP2PRT-PANUCP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdd79592-32b0-4b1f-a7b3-3b81ebb35aee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANUCP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANUCP-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e5397c8-cc6b-4a18-8435-05a843b0cdf5

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 27/382 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACKR3 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 210/603 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749662463; called by muse, mutect2, varscan2
- GRIA3 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 148/373 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs757586471, CM151043; called by muse, mutect2, varscan2
- GRM3 | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 142/547 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.771); catalogued as rs1294076381, COSV100862751; called by muse, mutect2, varscan2
- KRT6A | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 37/604 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as rs369800257; called by muse, mutect2
- LIN7A | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 21/389 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1565900469, COSV54019676; called by muse, mutect2
- MED12 | c.4907G>A p.R1636H | Missense Mutation (SNP) | VAF 224/551 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs968428355; called by muse, mutect2, varscan2
- MYH2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 192/718 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs578188627, COSV55443758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- P3H3 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 49/609 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.164); catalogued as rs1555121142; called by muse, mutect2
- XIRP2 | c.1852C>T p.R618* (on ENST00000628543; = p.R793* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 121/344 reads (35%) | catalogued as rs374843236, COSV99743895; called by muse, mutect2, varscan2
- XKR7 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 44/710 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73812911; called by muse, mutect2
- CPNE5 | c.137-4_161delinsCGCAGTGTGCGTCATTCGG p.X46_splice | Splice Site (DEL) | VAF 89/565 reads (16%) | called by pindel, varscan2*
- DNAH17 | c.4987C>T p.R1663* | Nonsense Mutation (SNP) | VAF 22/697 reads (3%) | called by muse, mutect2
- FLT3 | c.1727_1728del p.L576Pfs*11 | Frame Shift Del (DEL) | VAF 68/371 reads (18%) | called by mutect2, pindel*, varscan2*
- FSIP2 | c.11312C>T p.T3771I | Missense Mutation (SNP) | VAF 25/410 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- KMT2D | c.11306_11307del p.L3769Rfs*242 | Frame Shift Del (DEL) | VAF 188/660 reads (28%) | called by mutect2, pindel, varscan2
- MUC5B | c.13997C>A p.T4666K | Missense Mutation (SNP) | VAF 251/820 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.181); called by muse, varscan2
- ADAMTS13 | c.2370G>A p.Q790= | Silent (SNP) | VAF 290/750 reads (39%) | called by muse, varscan2
- FHDC1 | c.3060G>A p.P1020= | Silent (SNP) | VAF 223/896 reads (25%) | catalogued as rs986472114, COSV99471664; called by muse, mutect2, varscan2
- SH3RF2 | c.246C>T p.S82= | Silent (SNP) | VAF 145/618 reads (23%) | catalogued as rs1156459483; called by muse, mutect2, varscan2
- ZNF697 | c.654C>T p.A218= | Silent (SNP) | VAF 211/641 reads (33%) | catalogued as rs587735897; called by muse, mutect2, varscan2
